Somatic mutation profile of tumor specimen 0E0A0I from CCDI case PBCUYV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E0A0I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59d03328-9ab1-4896-bdf2-9b783c43a6f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0A0P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/542c9ef6-ecfd-4745-87cd-e1557ddd703f

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, Intron 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSP | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 158/649 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1233981969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MNT | c.211del p.A71Lfs*16 | Frame Shift Del (DEL) | VAF 70/133 reads (53%) | catalogued as COSV99438255; called by mutect2, varscan2
- ZNF534 | c.1133G>T p.R378L (on ENST00000332323 / NM_001143939.3; = p.R365L on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 160/1004 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.377); catalogued as COSV56516968; called by muse, varscan2
- BRINP1 | c.1109G>T p.C370F | Missense Mutation (SNP) | VAF 68/757 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- GRIN2D | c.3199G>A p.E1067K | Missense Mutation (SNP) | VAF 30/299 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZNF534 | c.1309G>A p.D437N (on ENST00000332323 / NM_001143939.3; = p.D424N on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 155/1004 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.331); called by muse, varscan2
- NDNF | c.283C>T p.L95= | Silent (SNP) | VAF 36/698 reads (5%) | catalogued as rs746133279; called by muse, mutect2
- ANKRD40CL | chr17:50767008 C>A | 5'Flank (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- FBXW5 | c.-23-24A>C | Intron (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
